MMRF case MMRF_1270 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3c13821d-8024-4b68-b927-014e00de6ddf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 45 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.0 years (23,752 days); ISS stage: II; Days to last known disease status: 45 days; Days to last follow up: 45 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 1, day 45.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL.
- Beta 2 Microglobulin 3.8 µg/mL.
- Platelets 155 ×10⁹/L.
- Absolute Neutrophil 2.4 ×10⁹/L.
- Glucose 4.51 mmol/L.
- Albumin 29 g/L.
- Immunoglobulin M 0.19 g/L.
- Total Protein 11.8 g/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 29.3 mg/dL.
- Hemoglobin 5.7 mmol/L.
- Immunoglobulin A 0.25 g/L.
- Calcium 2.18 mmol/L.
- Blood Urea Nitrogen 7.5 mmol/L.
- Lactate Dehydrogenase 3.35 µkat/L.
- M Protein 6.2 g/dL.
- Leukocytes 4.5 ×10⁹/L.
- Immunoglobulin G 83.3 g/L.
- Creatinine 69 µmol/L.

Other clinical attributes
- Day 1: Weight: 81 kg; Height: 156 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1270_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1270_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
